Somatic mutation profile of tumor specimen TCGA-23-1114-01B (aliquot TCGA-23-1114-01B-01W-0633-09) from TCGA case TCGA-23-1114, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.9 years (20,409 days).
Specimen TCGA-23-1114-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c5bdf56-06c8-4034-bf46-7b7cfa66155a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1114-10A (Blood Derived Normal), aliquot TCGA-23-1114-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e66b739d-7f4b-4e46-add8-df99da56e56a

The open-access MAF lists 145 somatic variants for this specimen: 112 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 30, Frame Shift Del 8, Splice Site 4, Nonsense Mutation 3, Frame Shift Ins 2, Nonstop Mutation 1, 5'UTR 1, RNA 1, In Frame Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+2T>G p.X307_splice | Splice Site (SNP) | VAF 382/484 reads (79%) | hotspot (GDC flag); catalogued as rs1131691016, COSV52698436, COSV52737448, COSV52774697; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57864241; called by muse, mutect2, varscan2
- ADRA1B | c.978dup p.D327Rfs*134 | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | catalogued as rs775788108; called by pindel, varscan2
- ALMS1 | c.2533G>A p.D845N | Missense Mutation (SNP) | VAF 83/339 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV52505697; called by muse, mutect2, varscan2
- ARFIP1 | c.285A>C p.L95F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.264); catalogued as COSV100617273; called by muse, mutect2
- ARHGAP20 | c.3514C>A p.P1172T | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.071); catalogued as COSV52808397, COSV52812075; called by muse, mutect2, varscan2
- ARSJ | c.432C>G p.I144M | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59537182; called by muse, mutect2, varscan2
- ATP2C2 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 20/309 reads (6%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.615); catalogued as rs771563962, COSV99298542; called by muse, mutect2
- B3GNT2 | c.358del p.L120Cfs*4 | Frame Shift Del (DEL) | VAF 123/536 reads (23%) | catalogued as COSV57344203; called by mutect2, pindel, varscan2
- BCAS3 | c.1510T>C p.Y504H | Missense Mutation (SNP) | VAF 162/856 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs994857524, COSV66771296; called by muse, mutect2, varscan2
- BRIP1 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99370813; called by muse, mutect2
- CACNA1G | c.7009T>A p.S2337T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV100662381; called by muse, mutect2
- CACNA1S | c.2809del p.L937Sfs*27 | Frame Shift Del (DEL) | VAF 71/155 reads (46%) | catalogued as COSV62939754; called by mutect2, pindel, varscan2
- CALCRL | c.1307G>C p.C436S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV66474093; called by muse, mutect2, varscan2
- CCDC141 | c.3291C>A p.H1097Q | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55383124; called by muse, mutect2
- CCDC180 | c.4600A>G p.R1534G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs772363374, COSV63828092; called by muse, mutect2, varscan2
- CHST14 | c.691C>G p.R231G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV60378505; called by muse, mutect2, varscan2
- COL24A1 | c.1502G>A p.G501D | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993881; called by muse, mutect2, varscan2
- COPS4 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV52314146; called by muse, mutect2, varscan2
- CPOX | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as COSV99939166; called by muse, mutect2
- CUZD1 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV59025992; called by muse, mutect2, varscan2
- CYB5R1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV100579635; called by muse, mutect2
- DDX53 | c.793G>T p.V265F | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100029065; called by muse, mutect2, varscan2
- DPPA3 | c.458A>G p.D153G | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV61502869; called by muse, mutect2, varscan2
- DRAXIN | c.757+1G>T p.X253_splice | Splice Site (SNP) | VAF 13/26 reads (50%) | catalogued as rs775953497, COSV53842267; called by muse, mutect2, varscan2
- EFCAB6 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99414200; called by muse, mutect2, varscan2
- EFCAB6 | c.1036G>T p.G346* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99414152, COSV99414201; called by muse, mutect2, varscan2
- EFNB1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV52661059, COSV99214841; called by muse, mutect2, varscan2
- ELAC2 | c.809C>A p.A270D | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100568611; called by muse, mutect2
- EPS8 | c.1100T>A p.M367K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV55528803; called by muse, mutect2, varscan2
- ERICH5 | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV59315389; called by muse, mutect2, varscan2
- F13B | c.1769A>G p.E590G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs1159470886, COSV66372934; called by muse, mutect2, varscan2
- FBXO38 | c.2043C>G p.I681M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57026547; called by muse, mutect2, varscan2
- FBXO46 | c.574C>G p.R192G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV58348114, COSV58349998; called by muse, mutect2, varscan2
- GATA3 | c.1175A>T p.N392I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV60516673; called by muse, mutect2, varscan2
- GFRA1 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62603737; called by muse, mutect2, varscan2
- GPR1 | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67976582; called by muse, mutect2, varscan2
- GPR37L1 | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100938584; called by muse, mutect2
- KCNA4 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1564936126, COSV60251254; called by muse, mutect2, varscan2
- KDM5A | c.1090C>A p.Q364K | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV101239035; called by muse, mutect2, varscan2
- KIAA1217 | c.1833A>T p.A611= | Splice Region (SNP) | VAF 8/134 reads (6%) | catalogued as COSV100287123; called by muse, mutect2
- KMT2A | c.526C>A p.R176S | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV63283648, COSV63286472, COSV63289560; called by muse, mutect2, varscan2
- LCE2B | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV64227401, COSV64227509; called by muse, mutect2, varscan2
- LNX1 | c.201C>A p.N67K | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99820319, COSV99820433; called by muse, mutect2
- LRP1B | c.9721C>G p.H3241D | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV67198968; called by muse, mutect2, varscan2
- MAG | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV62699687; called by muse, mutect2, varscan2
- MBD5 | c.3239C>T p.P1080L | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as COSV68696237; called by muse, mutect2, varscan2
- METTL16 | c.549C>A p.C183* | Nonsense Mutation (SNP) | VAF 10/210 reads (5%) | catalogued as COSV99563745; called by muse, mutect2
- MFN2 | c.1877G>T p.W626L | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.869); catalogued as COSV52421185; called by muse, mutect2, varscan2
- MUC13 | c.1225_1229del p.G409Qfs*6 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | catalogued as COSV60698944; called by mutect2, pindel, varscan2
- MYOC | c.1407C>G p.N469K | Missense Mutation (SNP) | VAF 127/430 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50674157; called by muse, mutect2, varscan2
- MYOZ1 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV63771674; called by muse, mutect2, varscan2
- NAGLU | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV56794372; called by muse, mutect2, varscan2
- NBPF10 | c.11266G>C p.V3756L | Missense Mutation (SNP) | VAF 86/1093 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV100745908, COSV61658414; called by muse, mutect2
- NMS | c.414G>T p.R138S | Missense Mutation (SNP) | VAF 11/249 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100966641; called by muse, mutect2
- NPC1L1 | c.1490A>G p.N497S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV56923495; called by muse, mutect2, varscan2
- NR4A2 | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV100277352; called by muse, mutect2
- NUP155 | c.3367C>G p.L1123V (on ENST00000231498 / NM_153485.3; = p.L1064V on NM_004298.4) | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as COSV51528019, COSV51528241; called by muse, mutect2, varscan2
- OR1J1 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52238036; called by muse, mutect2, varscan2
- OR2T11 | c.460T>A p.F154I | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV58185117; called by muse, mutect2, varscan2
- OR52R1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs150778227; called by muse, mutect2, varscan2
- PCDHB13 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV53394318, COSV53398477; called by muse, mutect2, varscan2
- PCDHB7 | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV50757983; called by muse, mutect2, varscan2
- PGAP4 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.395); catalogued as COSV66387332; called by muse, mutect2, varscan2
- PHKA1 | c.1780T>A p.F594I | Missense Mutation (SNP) | VAF 158/425 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.141); catalogued as COSV59803708; called by muse, mutect2, varscan2
- PLAC1 | c.281A>T p.Y94F | Missense Mutation (SNP) | VAF 62/329 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as COSV63655382; called by muse, mutect2, varscan2
- PLPP6 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV56304717; called by muse, mutect2, varscan2
- PMS1 | c.2249A>G p.Y750C | Missense Mutation (SNP) | VAF 116/279 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs774576220, COSV59715388; called by muse, mutect2, varscan2
- POLA2 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV55481623; called by muse, mutect2, varscan2
- POP1 | c.1893G>T p.W631C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62892190; called by muse, mutect2, varscan2
- PPP1R18 | c.1822+2T>A p.X608_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99223874; called by muse, mutect2
- PTPN13 | c.5363T>A p.L1788H (on ENST00000411767 / NM_080683.3; = p.L1769H on NM_006264.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57404359; called by muse, mutect2, varscan2
- PYHIN1 | c.628T>A p.F210I | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100932402; called by muse, mutect2
- RBM45 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV53720269; called by muse, varscan2
- REN | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV65817523; called by muse, mutect2, varscan2
- ROPN1 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs748387485, COSV51739433; called by mutect2, varscan2
- RPS10 | c.1-1G>T p.X1_splice | Splice Site (SNP) | VAF 6/51 reads (12%) | catalogued as COSV58241879; called by muse, mutect2, varscan2
- RPUSD4 | c.1097A>T p.N366I | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.08); catalogued as COSV53598922; called by muse, mutect2, varscan2
- RSBN1L | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV58506960; called by muse, mutect2, varscan2
- RYR2 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV100769976, COSV63672251; called by muse, mutect2, varscan2
- SAP130 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1206219314, COSV52103023; called by muse, mutect2
- SCAI | c.274G>A p.G92R (on ENST00000336505 / NM_001144877.3; = p.G115R on NM_173690.5) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60611078; called by muse, mutect2, varscan2
- SIDT1 | c.1075A>G p.I359V | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.171); catalogued as COSV53499452; called by muse, mutect2, varscan2
- SLC17A7 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55547010; called by muse, mutect2, varscan2
- SMARCA1 | c.2580G>C p.W860C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64411263; called by muse, mutect2, varscan2
- SRFBP1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as rs188297674, COSV100232912; called by muse, mutect2
- STARD8 | c.2078A>T p.E693V | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52923411; called by muse, mutect2, varscan2
- TENM2 | c.3694G>C p.A1232P (on ENST00000518659 / NM_001122679.2; = p.A1000P on NM_001080428.3) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69125324; called by muse, mutect2, varscan2
- TRAP1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV55915408; called by muse, mutect2, varscan2
- TRMT2B | c.197G>T p.S66I | Missense Mutation (SNP) | VAF 18/501 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV100105619; called by muse, mutect2
- TXNDC16 | c.1037_1038del p.H346Rfs*4 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | catalogued as rs1433099305, COSV55983757; called by mutect2, pindel, varscan2
- UNC80 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55886281; called by muse, mutect2, varscan2
- USP29 | c.1607G>C p.S536T | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV99518509; called by muse, mutect2
- USP51 | c.610G>C p.G204R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV101540691; called by mutect2, varscan2
- VCL | c.2065C>G p.Q689E | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV53007972; called by muse, mutect2, varscan2
- WDR13 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV54331193; called by muse, mutect2, varscan2
- WDR6 | c.3366A>C p.*1122Cext*86 | Nonstop Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV58244368; called by muse, mutect2, varscan2
- YARS2 | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 171/323 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV61401335; called by muse, mutect2, varscan2
- ZC4H2 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs958668037, COSV100565132, COSV62002663; called by muse, mutect2
- ZNF224 | c.808A>C p.I270L | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.474); catalogued as COSV61241881; called by muse, mutect2, varscan2
- ZNF749 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145828653; called by muse, mutect2, varscan2
- ABCA13 | c.9878_9901del p.L3293_L3300del | In Frame Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- DPYS | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 36/463 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM186B | c.1343del p.F448Sfs*18 | Frame Shift Del (DEL) | VAF 116/510 reads (23%) | called by mutect2, pindel, varscan2
- IGHV4-59 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 76/486 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGKV2D-24 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 52/367 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- IGKV2D-24 | c.301A>T p.S101C | Missense Mutation (SNP) | VAF 57/423 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- MED12 | c.5301dup p.K1768Qfs*3 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- NUF2 | c.187_196del p.H63* | Frame Shift Del (DEL) | VAF 39/138 reads (28%) | called by mutect2, pindel, varscan2
- PYGB | c.2446del p.R816Gfs*84 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel
- RPS14 | c.209_219del p.S70Cfs*31 | Frame Shift Del (DEL) | VAF 59/168 reads (35%) | called by mutect2, pindel, varscan2
- TBC1D3F | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- ADCY9 | c.3840C>T p.N1280= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV53572950, COSV99571004; called by muse, mutect2, varscan2
- AKAP12 | c.345G>C p.V115= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV53571650; called by muse, varscan2
- ARHGAP11A | c.2772C>G p.P924= | Silent (SNP) | VAF 6/138 reads (4%) | catalogued as COSV100276921; called by muse, mutect2
- CDH4 | c.1743C>T p.Y581= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs559348748, COSV64646283; called by muse, mutect2, varscan2
- CNN3 | c.978C>T p.G326= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as COSV54728509; called by muse, mutect2, varscan2
- CTNNBIP1 | c.204G>A p.V68= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV65962165; called by muse, mutect2, varscan2
- EPB42 | c.225C>A p.T75= (on ENST00000441366 / NM_001114134.2; = p.T105= on NM_000119.3) | Silent (SNP) | VAF 105/265 reads (40%) | catalogued as COSV55748959; called by muse, mutect2, varscan2
- FAT3 | c.7668A>G p.E2556= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV53089847; called by muse, mutect2, varscan2
- FTSJ3 | c.24C>G p.G8= | Silent (SNP) | VAF 59/78 reads (76%) | catalogued as COSV59561864; called by muse, mutect2, varscan2
- FUNDC2 | c.543A>G p.G181= | Silent (SNP) | VAF 60/353 reads (17%) | catalogued as COSV65670589; called by muse, mutect2, varscan2
- GFRA1 | c.447C>G p.P149= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV62603743; called by muse, mutect2, varscan2
- GUCY1A2 | c.510A>G p.Q170= | Silent (SNP) | VAF 52/86 reads (60%) | catalogued as COSV56481548; called by muse, mutect2, varscan2
- H2BC12 | c.264G>C p.S88= | Silent (SNP) | VAF 12/259 reads (5%) | catalogued as COSV63617840; called by muse, mutect2
- HIVEP1 | c.804T>C p.A268= | Silent (SNP) | VAF 269/748 reads (36%) | catalogued as COSV65099777; called by muse, mutect2, varscan2
- ITPRID1 | c.189G>A p.Q63= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV60071857; called by muse, mutect2, varscan2
- KCNK13 | c.468C>T p.I156= | Silent (SNP) | VAF 108/231 reads (47%) | catalogued as COSV56411637; called by muse, mutect2, varscan2
- KNTC1 | c.39C>T p.T13= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as rs763877172, COSV59203526; called by muse, mutect2, varscan2
- MARCHF6 | c.2043T>G p.G681= | Silent (SNP) | VAF 32/266 reads (12%) | catalogued as COSV56879706; called by muse, mutect2, varscan2
- MICAL2 | c.2397C>A p.G799= | Silent (SNP) | VAF 6/103 reads (6%) | catalogued as COSV99818191; called by muse, mutect2
- NAV2 | c.6321G>C p.L2107= (on ENST00000396087 / NM_001244963.2; = p.L2048= on NM_145117.5) | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV100217547; called by muse, mutect2
- NPC1 | c.2427C>T p.S809= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as rs745542071, COSV52576635; called by muse, mutect2, varscan2
- OR10H1 | c.99G>T p.L33= | Silent (SNP) | VAF 81/639 reads (13%) | catalogued as COSV58471021; called by muse, mutect2, varscan2
- OR4K14 | c.291A>G p.G97= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV59292421; called by muse, mutect2, varscan2
- PAK3 | c.1251A>G p.K417= (on ENST00000262836 / NM_001324328.2; = p.K402= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 12/223 reads (5%) | called by muse, mutect2
- PEX5 | c.1275C>T p.T425= (on ENST00000420616; = p.T417= on NM_000319.5) | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV56953797; called by muse, mutect2, varscan2
- PLXDC2 | c.1419G>C p.V473= | Silent (SNP) | VAF 179/587 reads (30%) | catalogued as COSV65901965, COSV65904207; called by muse, mutect2, varscan2
- PRDM5 | c.229C>A p.R77= | Silent (SNP) | VAF 115/618 reads (19%) | catalogued as COSV53357690, COSV53357756; called by muse, mutect2, varscan2
- SNRPB | c.18C>T p.S6= | Silent (SNP) | VAF 100/415 reads (24%) | catalogued as rs745345351, COSV60015188; called by muse, mutect2, varscan2
- TEX47 | c.15C>T p.V5= | Silent (SNP) | VAF 40/285 reads (14%) | catalogued as COSV51878478; called by muse, mutect2, varscan2
- XIRP2 | c.1329A>C p.T443= (on ENST00000628543; = p.T618= on NM_152381.6) | Silent (SNP) | VAF 7/169 reads (4%) | catalogued as COSV99746435; called by muse, mutect2
- AL590867.2 | n.239C>T | RNA (SNP) | VAF 57/318 reads (18%) | called by muse, mutect2, varscan2
- CSN2 | c.-1C>T | 5'UTR (SNP) | VAF 23/74 reads (31%) | catalogued as rs562253705, COSV100778817; called by muse, mutect2, varscan2
- CTHRC1 | c.150+792C>G | Intron (SNP) | VAF 8/92 reads (9%) | catalogued as rs1313330982; called by mutect2, varscan2
